Surgical pathology report (de-identified scan), TCGA case TCGA-78-7149, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7149-01A (Primary Tumor).

HISTORY
RLL lesion.

MACROSCOPIC
Two specimens submitted.

1: The first specimen is labelled "right lower lobectomy" and consists of a right lower lobectomy specimen which measures 70 x 80 x 60 mm. Sectioning reveals a large tumour present predominantly in the superior aspect of the lobe which measures 75 x 60 x 60 mm. The tumour has a pink and tan colour and has a soft consistency. The tumour reaches the pleura but no definite invasion through the pleura is seen grossly. The tumour extensively invades around bronchi and at one point tumour is seen to erode through the bronchial wall to form a polypoid mass measuring up to 10 mm within the bronchial lumen. This is present approximately 14 mm away from the nearest bronchial resection margin. The tumour appears to come within approximately 2 mm of the hilar resection margin but tumour is not seen at a surgical resection margin. Located away from the main tumour within the inferomedial aspect of the lung are three separate tumour nodules measuring between 5 to 12 mm in diameter. An area of fibrosis and calcification measuring up to 3 mm in diameter is also seen within the region of one of the separate tumour nodules in the inferior aspect of the lobe. Lung tissue at the superior aspect of the lobe proximal to the tumour shows yellow discolouration. The lung in the inferior aspect of the lobe distal to the tumour appears fairly unremarkable. [1A, bronchial and hilar vascular resection margins; 1B, vascular resection margin and lymph nodes; 1C-1G, tumour with 1D being mediastinal resection margin, 1E bronchus with invasion by tumour; 1G-1I, separate tumour deposits inferior to the main tumour; 1J, uninvolved lung proximal to tumour; 1K, uninvolved lung distal to tumour.]

2: The second specimen is labelled "hilar lymph node" and consists of multiple fragments of grey tissue measuring in aggregate approximately 20 x 20 x 5 mm. [BIT, 2A.]

MICROSCOPY

1: Sections show a moderately differentiated adenocarcinoma. Much of the tumour has the cytoarchitectural features of a non-mucinous bronchioloalveolar carcinoma, but unequivocal stromal invasion is present, and an endobronchial component is confirmed. Tumour abuts but does not invade the pleura, and the bronchial and mediastinal resection margins are clear of malignancy. No vascular or lymphatic invasion is identified. Peribronchial lymph nodes show no evidence of metastatic adenocarcinoma. Several satellite nodules are confirmed in lung parenchyma inferior to the main tumour mass. These show the BAC architecture and presumably represent spread through airways.

2: Sections show fragments of lymph node in which there is no evidence of metastatic adenocarcinoma.

SUMMARY

Right lower lobectomy: Moderately differentiated adenocarcinoma with a large component of bronchioloalveolar carcinoma, 75 mm in diameter, with adjacent satellite nodules.

No pleural, vascular, lymphatic or perineural infiltration present.

No lymph node metastases.

Pathological stage T4 N0.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file dafca9ff-1c2b-44fd-a654-e3ec35d9ee7c (TCGA-78-7149.2211DCAB-03DD-493C-9131-684A9ACCEA7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).